MMRF case MMRF_1424 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3b14eb0d-8007-4a10-b64a-ee7f9799b9a0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 40 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 40.5 years (14,797 days); ISS stage: III; Days to last known disease status: 1,446 days (4.0 years); Days to last follow up: 1,446 days (4.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 95 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 109 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 150 days; Days to treatment end: 192 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 214 days; Days to treatment end: 214 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 247 days; Days to treatment end: 248 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 250 days; Days to treatment end: 250 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 361 days; Days to treatment end: 473 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 586 days (1.6 years); Days to treatment end: 676 days (1.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 677 days (1.9 years); Days to treatment end: 926 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 981 days (2.7 years); Days to treatment end: 1,278 days (3.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,376 days (3.8 years); Days to treatment end: 1,377 days (3.8 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,376 days (3.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,383 days (3.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 445 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.62 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 4.06 g/L; Immunoglobulin M 0.62 g/L; Beta 2 Microglobulin 6.24 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.55 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 4.95 mmol/L; C-Reactive Protein 1.32 mg/dL.
- Day 85: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.93 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 1.95 g/L; Immunoglobulin M 0.72 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 5.8 g/dL; Glucose 4.9 mmol/L.
- Day 176 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 3.61 g/L; Immunoglobulin M 1.42 g/L; Beta 2 Microglobulin 4.2 µg/mL; Hemoglobin 7.75 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 33 g/L; Total Protein 7.4 g/dL; Glucose 7.54 mmol/L.
- Day 264 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.62 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 2.58 g/L; Immunoglobulin M 0.96 g/L; Beta 2 Microglobulin 5.54 µg/mL; Hemoglobin 6.2 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 42 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 1.07 mmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 5.5 g/dL; Glucose 5.78 mmol/L.
- Day 361 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 5.78 mmol/L.
- Day 443: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.97 mg/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 1.35 g/L; Immunoglobulin M 0.7 g/L; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 5.83 mmol/L.
- Day 529 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.14 mg/dL; Immunoglobulin G 21.4 g/L; Immunoglobulin A 1.72 g/L; Immunoglobulin M 0.75 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 7.3 g/dL; Glucose 5.78 mmol/L.
- Day 627: M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.98 mg/dL; Immunoglobulin G 23.3 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.68 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.12 mmol/L.
- Day 718: Serum Free Immunoglobulin Light Chain, Kappa 48.4 mg/dL; Immunoglobulin G 19 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 1.7 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 5.01 mmol/L.
- Day 802: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.65 mg/dL; Immunoglobulin G 16.2 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.56 mmol/L.
- Day 886 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.8 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 1.47 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.05 mmol/L; Albumin 31 g/L; Total Protein 6.4 g/dL; Glucose 5.34 mmol/L.
- Day 985 (ECOG 0): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.67 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 288 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 5.12 mmol/L.
- Day 1,068 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.83 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.03 mmol/L; Albumin 32 g/L; Total Protein 6 g/dL; Glucose 4.35 mmol/L.
- Day 1,166 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.19 mg/dL; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 284 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.34 mmol/L.
- Day 1,250 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.05 mg/dL; Immunoglobulin G 17.2 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 5.12 mmol/L.
- Day 1,324 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 68.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.32 mg/dL; Immunoglobulin G 16.4 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 295 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL; Glucose 6.88 mmol/L.
- Day 1,446 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.58 mg/dL; Immunoglobulin G 9.16 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2 mmol/L; Albumin 33 g/L; Total Protein 6 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day -6: Weight: 101 kg; Height: 167 cm.

Biospecimens (4 samples)
- Sample MMRF_1424_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1424_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
- Sample MMRF_1424_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 85 days.
- Sample MMRF_1424_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 85 days.
